Somatic mutation profile of tumor specimen MP2PRT-PANXSV-TMP1-A (aliquot MP2PRT-PANXSV-TMP1-A-1-0-D-A82K-36) from MP2PRT case MP2PRT-PANXSV, project MP2PRT-ALL (Molecular Profiling to Predict Response to Treatment for Acute Lymphoblastic Leukemia). Sex at birth: male; Primary diagnosis: Common precursor B ALL; Tissue or organ of origin: Bone marrow; Age at diagnosis: 4.3 years (1,584 days).
Specimen MP2PRT-PANXSV-TMP1-A: Sample type: Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Whole Bone Marrow; Biospecimen anatomic site: Bone Marrow; Preservation method: Cryopreserved.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 33c02905-d8ed-4b8c-9a2e-926e841d59c4.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MP2PRT-PANXSV-NB1-A (Blood Derived Cancer - Peripheral Blood, Post-treatment; tissue type Normal — post-treatment blood used as the germline comparator), aliquot MP2PRT-PANXSV-NB1-A-1-0-D-A82K-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/faa4eea9-4927-4fa4-bb47-154d6a97cfbe

The open-access MAF lists 44 somatic variants for this specimen: 34 protein-altering or splice-affecting, 9 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 31, Silent 9, Nonsense Mutation 2, Intron 1, Splice Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ANKRD39 | c.485G>A p.R162Q | Missense Mutation (SNP) | VAF 37/712 reads (5%) | SIFT tolerated (0.53); PolyPhen benign (0); catalogued as rs147578390; called by muse, mutect2
- BAP1 | c.2137C>T p.R713W | Missense Mutation (SNP) | VAF 301/794 reads (38%) | SIFT deleterious (0); PolyPhen possibly damaging (0.719); catalogued as COSV56231920; called by muse, mutect2, varscan2
- COL21A1 | c.563C>G p.S188C | Missense Mutation (SNP) | VAF 27/383 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.947); catalogued as rs770795657; called by muse, mutect2
- DOCK1 | c.542C>T p.T181M | Missense Mutation (SNP) | VAF 114/320 reads (36%) | SIFT deleterious (0); PolyPhen possibly damaging (0.893); catalogued as rs770984148, COSV99726250; called by muse, mutect2, varscan2
- EFNB3 | c.717G>T p.L239F | Missense Mutation (SNP) | VAF 375/928 reads (40%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.959); catalogued as rs776862628; called by muse, mutect2, varscan2
- FARP1 | c.2434-1G>A p.X812_splice | Splice Site (SNP) | VAF 190/481 reads (40%) | catalogued as rs1383256719, COSV60343606; called by muse, mutect2, varscan2
- FGL1 | c.647C>T p.A216V | Missense Mutation (SNP) | VAF 226/479 reads (47%) | SIFT tolerated (0.11); PolyPhen benign (0.137); catalogued as rs766665979, COSV67711991; called by muse, mutect2, varscan2
- LRGUK | c.676G>C p.E226Q | Missense Mutation (SNP) | VAF 98/217 reads (45%) | SIFT tolerated (0.32); PolyPhen benign (0.007); catalogued as COSV53637236, COSV53643640; called by muse, mutect2, varscan2
- PLOD1 | c.871G>A p.G291S | Missense Mutation (SNP) | VAF 80/572 reads (14%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.891); catalogued as rs776772692; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- SAMD3 | c.910G>A p.E304K | Missense Mutation (SNP) | VAF 20/576 reads (3%) | SIFT tolerated (0.29); PolyPhen probably damaging (0.994); catalogued as COSV63719591; called by muse, mutect2
- SLC32A1 | c.580T>C p.C194R | Missense Mutation (SNP) | VAF 37/1118 reads (3%) | SIFT deleterious (0.01); PolyPhen benign (0.179); catalogued as COSV54146431; called by muse, mutect2
- SYDE2 | c.3173G>A p.R1058Q | Missense Mutation (SNP) | VAF 38/444 reads (9%) | SIFT deleterious (0.05); PolyPhen benign (0.057); catalogued as rs755225039, COSV58326449; called by muse, mutect2
- TRIM33 | c.316G>A p.A106T | Missense Mutation (SNP) | VAF 184/864 reads (21%) | SIFT tolerated, low confidence (0.18); PolyPhen benign (0); catalogued as rs763585538; called by muse, mutect2, varscan2
- C12orf40 | c.1546A>G p.M516V | Missense Mutation (SNP) | VAF 50/170 reads (29%) | SIFT tolerated (1); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- CGAS | c.256C>G p.Q86E | Missense Mutation (SNP) | VAF 29/1121 reads (3%) | SIFT tolerated (0.2); PolyPhen benign (0); called by muse, mutect2
- COL3A1 | c.2759C>T p.S920F | Missense Mutation (SNP) | VAF 22/612 reads (4%) | SIFT tolerated (0.21); PolyPhen benign (0.062); called by muse, mutect2
- CUL9 | c.2902G>T p.E968* | Nonsense Mutation (SNP) | VAF 65/731 reads (9%) | called by muse, mutect2
- DDX60 | c.4949C>A p.S1650Y | Missense Mutation (SNP) | VAF 121/376 reads (32%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.935); called by muse, mutect2, varscan2
- ECEL1 | c.451G>A p.A151T | Missense Mutation (SNP) | VAF 29/855 reads (3%) | SIFT tolerated (0.6); PolyPhen benign (0.02); called by muse, mutect2
- HEG1 | c.1312C>G p.Q438E | Missense Mutation (SNP) | VAF 48/535 reads (9%) | SIFT tolerated (0.13); PolyPhen benign (0.13); called by muse, mutect2
- IFNAR1 | c.1057C>A p.P353T | Missense Mutation (SNP) | VAF 36/472 reads (8%) | SIFT deleterious (0.05); PolyPhen benign (0.3); called by muse, mutect2
- MCF2 | c.1926G>C p.L642F | Missense Mutation (SNP) | VAF 17/115 reads (15%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- MIA2 | c.259G>C p.E87Q | Missense Mutation (SNP) | VAF 9/205 reads (4%) | SIFT deleterious (0.01); PolyPhen benign (0.248); called by muse, mutect2
- MKRN3 | c.1128C>G p.F376L | Missense Mutation (SNP) | VAF 21/519 reads (4%) | SIFT deleterious (0.01); PolyPhen benign (0.409); called by muse, mutect2
- MPDZ | c.3083G>T p.G1028V | Missense Mutation (SNP) | VAF 164/345 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by mutect2, varscan2
- OR51F1 | c.502C>A p.L168I | Missense Mutation (SNP) | VAF 133/359 reads (37%) | SIFT tolerated (0.1); PolyPhen benign (0.094); called by muse, mutect2, varscan2
- PABPC1 | c.70G>A p.E24K | Missense Mutation (SNP) | VAF 38/679 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- PCARE | c.3694G>A p.D1232N | Missense Mutation (SNP) | VAF 72/763 reads (9%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.946); called by muse, mutect2
- POU5F1 | c.1057C>G p.L353V | Missense Mutation (SNP) | VAF 20/458 reads (4%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.883); called by muse, mutect2
- SEC31B | c.2320C>G p.Q774E | Missense Mutation (SNP) | VAF 13/356 reads (4%) | SIFT tolerated (0.36); PolyPhen benign (0.003); called by muse, mutect2
- TCFL5 | c.616G>C p.E206Q | Missense Mutation (SNP) | VAF 14/426 reads (3%) | SIFT tolerated (0.23); PolyPhen benign (0.262); called by muse, mutect2
- TRMT44 | c.1939C>G p.L647V | Missense Mutation (SNP) | VAF 17/411 reads (4%) | SIFT tolerated (0.14); PolyPhen benign (0.21); called by muse, mutect2
- YTHDC1 | c.2114G>A p.R705K (on ENST00000344157 / NM_001031732.4; = p.R687K on NM_133370.4) | Missense Mutation (SNP) | VAF 188/530 reads (35%) | SIFT tolerated, low confidence (0.26); PolyPhen possibly damaging (0.899); called by muse, mutect2, varscan2
- ZFPM2 | c.1498C>T p.Q500* | Nonsense Mutation (SNP) | VAF 141/371 reads (38%) | called by muse, mutect2, varscan2
- AP3B2 | c.1692G>A p.L564= | Silent (SNP) | VAF 155/404 reads (38%) | called by muse, mutect2, varscan2
- CARF | c.1653C>G p.L551= | Silent (SNP) | VAF 27/436 reads (6%) | catalogued as COSV57546852; called by muse, mutect2
- CARMIL3 | c.3261G>A p.P1087= | Silent (SNP) | VAF 34/420 reads (8%) | catalogued as rs1296921400; called by muse, mutect2
- DNAJC16 | c.978C>T p.L326= | Silent (SNP) | VAF 119/327 reads (36%) | called by muse, mutect2, varscan2
- MTHFD2L | c.306G>A p.K102= (on ENST00000395759 / NM_001144978.2; = p.K44= on NM_001004346.4 and 2 other RefSeq transcripts) | Silent (SNP) | VAF 12/236 reads (5%) | catalogued as COSV57466979; called by muse, mutect2
- MYADML2 | c.537C>T p.F179= | Silent (SNP) | VAF 35/884 reads (4%) | catalogued as rs1029756332, COSV57998920; called by muse, mutect2
- PHF20L1 | c.1050G>A p.K350= | Silent (SNP) | VAF 60/589 reads (10%) | called by muse, mutect2, varscan2
- POLQ | c.846C>T p.L282= | Silent (SNP) | VAF 189/539 reads (35%) | called by muse, mutect2, varscan2
- UGGT2 | c.816C>G p.L272= | Silent (SNP) | VAF 89/255 reads (35%) | catalogued as rs139386864; called by muse, mutect2, varscan2
- SNCAIP | c.58-2765G>A | Intron (SNP) | VAF 41/619 reads (7%) | called by muse, mutect2
